Gene-level copy-number profile of tumor specimen TCGA-KQ-A41Q-01A from TCGA case TCGA-KQ-A41Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-KQ-A41Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.19d669fd-78c5-46d6-a7f0-c127a35986fe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41Q-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8061a80-ca11-4eca-8e39-b23fb402c019

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 532; copy number 2: 23,176; copy number 3: 24,946; copy number 4: 6,008; copy number 5: 3,941; copy number 6: 247; copy number 7: 270; copy number 8: 107; copy number 9: 88; copy number 10: 86; copy number 11: 70; copy number 12: 151; copy number 13: 13; copy number 14: 39; copy number 15: 95; copy number 16: 7; copy number 20: 1; copy number 21: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41Q-01A-11D-A338-01): tumor purity 0.6, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:73,151,241–73,264,480, 1 gene: LINC02864.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 965 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:58,562,160–60,038,586, 14 genes, copy number 9–12: AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:76,435,229–78,008,688, 31 genes, copy number 7: SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3.
- chr6:17,015,817–21,602,383, 62 genes, copy number 7–16 (broad region; genes not listed).
- chr7:15,200,317–17,558,909, 35 genes, copy number 13–21 (within-gene range 6–21): AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr8:105,287,830–107,648,032, 22 genes, copy number 10: AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13.
- chr8:139,727,725–141,344,621, 25 genes, copy number 7 (within-gene range 5–7): TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300.
- chr10:7,158,624–8,162,192, 16 genes, copy number 8–13: SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1.
- chr10:8,897,989–9,724,416, 5 genes, copy number 8–20: LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P.
- chr11:57,576,292–60,507,430, 134 genes, copy number 7–11 (broad region; genes not listed).
- chr12:66,767–4,851,927, 122 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr12:7,566,369–10,613,609, 165 genes, copy number 12–14 (broad region; genes not listed).
- chr20:30,484,925–32,858,751, 76 genes, copy number 8–10 (broad region; genes not listed).
- chr20:33,358,839–36,088,192, 106 genes, copy number 7–8 (broad region; genes not listed).
- chr20:42,072,752–45,725,830, 106 genes, copy number 15–21 (within-gene range 2–21) (broad region; genes not listed).
- chr20:47,160,838–47,904,423, 18 genes, copy number 7: AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P.
- chr22:37,225,270–37,849,327, 28 genes, copy number 9: RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0, GCAT, GALR3, ANKRD54, MIR658, MIR659.

Autosomal genes at a single copy (total copy number 1): 532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
